Somatic mutation profile of tumor specimen MP2PRT-PARJFU-TMP1-B (aliquot MP2PRT-PARJFU-TMP1-B-1-0-D-A834-36) from MP2PRT case MP2PRT-PARJFU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,580 days).
Specimen MP2PRT-PARJFU-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e7ae48d-0e7e-4e30-974c-41f07ab599e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARJFU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARJFU-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79aa36ab-12f6-4730-a839-2cfa44dc0006

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 29/731 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as rs903105349, COSV52039695, COSV52040831; called by muse, mutect2
- ARPP21 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 83/942 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs774708704; called by muse, mutect2
- CCDC113 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 198/516 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs780838577, COSV54685884, COSV54687144; called by muse, mutect2, varscan2
- KCNQ2 | c.1477C>T p.R493C (on ENST00000359125 / NM_172107.4; = p.R465C on NM_004518.6) | Missense Mutation (SNP) | VAF 320/879 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs759338332; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSMCE1 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 191/500 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs759281877, COSV63864627; called by muse, mutect2, varscan2
- TM9SF2 | c.170_171+2delinsCCGGTCGG p.X57_splice | Splice Site (INS) | VAF 113/430 reads (26%) | called by pindel, varscan2*
- ABRA | c.468C>T p.S156= | Silent (SNP) | VAF 229/565 reads (41%) | called by muse, mutect2, varscan2
- NUP98 | chr11:3797980 A>T | 5'Flank (SNP) | VAF 30/595 reads (5%) | called by muse, mutect2
